Gene-level copy-number profile of tumor specimen TCGA-HQ-A5NE-01A from TCGA case TCGA-HQ-A5NE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 56.5 years (20,647 days).
Specimen TCGA-HQ-A5NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.dea39ebd-9b3d-4bf0-81ce-6f25116e9abc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HQ-A5NE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/196ddf47-8a09-448a-9ed8-7305d96784f3

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 40,391; copy number 2: 15,435; copy number 3: 2,472; copy number 4: 1,414; copy number 5: 23; copy number 9: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HQ-A5NE-01A-12D-A288-01): tumor purity 0.26, ploidy 4.55, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,340,797–51,767,709, 78 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,874 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:118,766,965–118,847,648, 2 genes, copy number 4: LINC01956, EN1.
- chr2:119,544,432–124,025,173, 53 genes, copy number 4–9 (within-gene range 2–9): CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1.
- chr2:126,109,761–126,702,942, 9 genes, copy number 3: LINC01941, AC142116.2, AC023347.1, SLC6A14P3, YWHAZP2, AC013474.2, GYPC, AC013474.1, RNU6-675P.
- chr5:58,198–45,895,970, 710 genes, copy number 4 (broad region; genes not listed).
- chr6:167,607–58,438,364, 1,527 genes, copy number 3 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 4 (broad region; genes not listed).
- chr16:65,861,112–76,819,624, 387 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr18:47,390–9,862,551, 199 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr20:87,250–16,983,033, 312 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 38,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
